Somatic mutation profile of tumor specimen 0DU3KX from CCDI case PBCKNA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.2 years (6,278 days).
Specimen 0DU3KX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88142bdc-0f53-4e38-90b0-e73a4c47e615.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU3MR (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a9e5543c-6225-4c76-b983-6ab72ba24356

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 3 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 3, 3'UTR 1, 5'Flank 1, Frame Shift Ins 1, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KDM1A | c.1135G>A p.E379K | Missense Mutation (SNP) | VAF 199/424 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs864309715, COSV63086495; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CIDEA | c.493G>A p.G165R | Missense Mutation (SNP) | VAF 232/486 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV100254784, COSV57597782; called by muse, mutect2, varscan2
- KRT9 | c.1211G>A p.R404H | Missense Mutation (SNP) | VAF 223/519 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs762146872, COSV55852540; called by muse, mutect2, varscan2
- TMEM161A | c.232C>T p.R78* | Nonsense Mutation (SNP) | VAF 282/592 reads (48%) | catalogued as rs759214004; called by muse, mutect2, varscan2
- TOGARAM2 | c.425G>A p.R142Q | Missense Mutation (SNP) | VAF 129/253 reads (51%) | SIFT tolerated (0.44); PolyPhen benign (0.022); catalogued as rs373400967; called by muse, mutect2, varscan2
- CCDC71L | c.20G>T p.R7M | Missense Mutation (SNP) | VAF 306/710 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KDM1A | c.2248C>T p.R750C | Missense Mutation (SNP) | VAF 223/480 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MGAT3 | c.641T>A p.V214D | Missense Mutation (SNP) | VAF 202/444 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- PTCH1 | c.3478dup p.T1160Nfs*24 | Frame Shift Ins (INS) | VAF 596/1012 reads (59%) | called by pindel, varscan2
- TGIF2 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 163/356 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.649); called by muse, mutect2, varscan2
- FOXD4L4 | c.30C>T p.R10= | Silent (SNP) | VAF 207/774 reads (27%) | called by muse, mutect2
- TENT5D | c.867A>C p.I289= | Silent (SNP) | VAF 265/269 reads (99%) | called by muse, mutect2, varscan2
- TPRX1 | c.1014C>T p.P338= | Silent (SNP) | VAF 292/617 reads (47%) | catalogued as rs369241122; called by muse, mutect2, varscan2
- NWD2 | c.*39G>A | 3'UTR (SNP) | VAF 87/180 reads (48%) | catalogued as rs945487342; called by muse, mutect2, varscan2
- PPP5C | c.1135+56C>G | Intron (SNP) | VAF 73/147 reads (50%) | called by muse, mutect2, varscan2
- ZGRF1 | chr4:112633187 G>T | 5'Flank (SNP) | VAF 112/268 reads (42%) | called by muse, mutect2, varscan2
